Somatic mutation profile of tumor specimen MP2PRT-PAUILL-TMP1-A (aliquot MP2PRT-PAUILL-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUILL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.4 years (2,347 days).
Specimen MP2PRT-PAUILL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83b680da-321b-4a39-b6a3-0a3dc58aecb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUILL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUILL-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b758ece0-4476-4f6b-bdd1-583d34fad005

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, 5'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 44/270 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- SLC26A9 | c.2126A>T p.D709V | Missense Mutation (SNP) | VAF 11/342 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs905648898; called by muse, mutect2
- VIPR2 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 120/374 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs750654613, COSV51105842; called by muse, mutect2, varscan2
- INTS10 | c.479T>C p.I160T | Missense Mutation (SNP) | VAF 47/216 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCDHB7 | c.2203G>A p.V735M | Missense Mutation (SNP) | VAF 130/1586 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.213); called by muse, mutect2
- RALGPS1 | c.849_850insGGG p.S283_L284insG | In Frame Ins (INS) | VAF 45/291 reads (15%) | called by mutect2, pindel, varscan2
- SLC47A2 | c.1739C>A p.A580D | Missense Mutation (SNP) | VAF 63/459 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- TSPY1 | c.292C>A p.P98T | Missense Mutation (SNP) | VAF 282/1201 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.129); called by muse, varscan2
- CIC | c.1785C>T p.D595= | Silent (SNP) | VAF 133/599 reads (22%) | catalogued as rs975540618; called by muse, mutect2, varscan2
- EXO1 | c.1813C>T p.L605= | Silent (SNP) | VAF 96/338 reads (28%) | called by muse, varscan2
- PLEKHH2 | c.2355G>A p.L785= | Silent (SNP) | VAF 106/324 reads (33%) | catalogued as COSV56758537; called by muse, mutect2, varscan2
- PLG | c.876C>A p.S292= | Silent (SNP) | VAF 85/470 reads (18%) | catalogued as COSV51983450; called by muse, mutect2, varscan2
- PRRT3 | c.2127C>T p.H709= | Silent (SNP) | VAF 237/606 reads (39%) | catalogued as rs760932331; called by muse, mutect2, varscan2
- DCLK3 | c.-335G>A | 5'UTR (SNP) | VAF 43/359 reads (12%) | catalogued as rs1378902984; called by muse, mutect2, varscan2
